Somatic mutation profile of tumor specimen C3L-00795-01 (aliquot CPT0390400006) from CPTAC case C3L-00795, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 69.5 years (25,383 days).
Specimen C3L-00795-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f552b86-cf29-4d9b-96f9-3ec81c67aa8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00795-31 (Blood Derived Normal), aliquot CPT0390460002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64bfad47-78ca-46c8-873f-204a93508604

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 1, 5'Flank 1, RNA 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIAS1 | c.238G>C p.V80L | Missense Mutation (SNP) | VAF 132/334 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV51036924; called by muse, mutect2, varscan2
- ATL3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CENPE | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD3 | c.912G>T p.E304D | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FGD3 | c.913C>A p.L305M | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- GDF11 | c.875del p.N292Tfs*191 | Frame Shift Del (DEL) | VAF 31/96 reads (32%) | called by mutect2, pindel, varscan2
- LAMA2 | c.2128T>C p.S710P | Missense Mutation (SNP) | VAF 130/411 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAT4C | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- OR2A25 | c.772T>G p.Y258D | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF111 | c.1198G>C p.A400P | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- UBE3C | c.997_1002del p.L333_S334del | In Frame Del (DEL) | VAF 42/109 reads (39%) | called by mutect2, pindel
- YTHDF3 | c.353T>G p.F118C | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2
- ARFGEF1 | c.4470G>A p.Q1490= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- CARD10 | c.2448G>T p.P816= | Silent (SNP) | VAF 146/476 reads (31%) | called by muse, mutect2, varscan2
- PTPRU | c.912C>A p.I304= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2
- YTHDF3 | c.351A>C p.P117= | Silent (SNP) | VAF 46/139 reads (33%) | called by muse, mutect2
- AC083864.1 | n.331C>G | RNA (SNP) | VAF 37/153 reads (24%) | called by muse, mutect2, varscan2
- C4B | chr6:32011016 C>T | 5'Flank (SNP) | VAF 196/559 reads (35%) | catalogued as rs1253925459; called by muse, varscan2
- LIMCH1 | c.936-6182A>G | Intron (SNP) | VAF 61/190 reads (32%) | catalogued as rs1460584853; called by muse, mutect2, varscan2
